Somatic mutation profile of tumor specimen MP2PRT-PATYDT-TMP1-A (aliquot MP2PRT-PATYDT-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATYDT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (829 days).
Specimen MP2PRT-PATYDT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05f3bbc4-a9ad-46f8-a127-ef4585e93742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYDT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYDT-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b506ac25-9ae5-448a-83ce-bf644f51d0d1

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 5, In Frame Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2
- FSIP2 | c.11588C>T p.P3863L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs529845185; called by muse, mutect2, varscan2
- IL7R | c.726_727insGGGTGCAGGCGTGAA p.L242_L243insGCRRE | In Frame Ins (INS) | VAF 41/238 reads (17%) | catalogued as COSV57415806; called by mutect2, pindel, varscan2
- STAMBPL1 | c.903G>A p.L301= | Splice Region (SNP) | VAF 46/116 reads (40%) | catalogued as rs1354662803; called by muse, mutect2, varscan2
- CDAN1 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- FMN2 | c.4531G>C p.A1511P | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAD1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA3 | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 109/306 reads (36%) | called by muse, mutect2, varscan2
- APLP1 | c.117C>T p.S39= | Silent (SNP) | VAF 24/441 reads (5%) | called by muse, mutect2
- GAL3ST1 | c.570C>T p.G190= | Silent (SNP) | VAF 85/382 reads (22%) | catalogued as rs1370792385; called by muse, mutect2, varscan2
- KCNT1 | c.1365C>T p.R455= (on ENST00000488444; = p.R474= on NM_020822.3) | Silent (SNP) | VAF 112/276 reads (41%) | catalogued as rs372250372; ClinVar: likely benign / benign; called by muse, varscan2
- MGAM2 | c.2373C>T p.I791= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs1237847152; called by muse, mutect2, varscan2
- MRGPRE | c.303G>A p.T101= | Silent (SNP) | VAF 83/410 reads (20%) | catalogued as rs773736351; called by muse, mutect2, varscan2
- QPCTL | c.873G>T p.R291= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as COSV50004295; called by muse, mutect2, varscan2
